Gene-level copy-number profile of tumor specimen TARGET-40-PANGPE-01A from TARGET case TARGET-40-PANGPE, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.1 years (4,794 days).
Specimen TARGET-40-PANGPE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.c0617670-3759-5394-a483-4c059e4fd2f2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANGPE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate.
https://portal.gdc.cancer.gov/files/2a00c7d7-3644-4f5d-a1bb-38a63253af75

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 35; copy number 2: 4,171; copy number 3: 9,222; copy number 4: 8,445; copy number 5: 9,358; copy number 6: 23,814; copy number 7: 1,589; copy number 8: 2,180; copy number 9: 455; copy number 10: 110; copy number 11: 1; copy number 13: 4; copy number 14: 72; copy number 15: 1; copy number 16: 188; copy number 17: 158; copy number 18: 53; copy number 20: 72; copy number 21: 214; copy number 24: 82; copy number 26: 43; copy number 41: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 888 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:139,716,753–140,154,184, 1 gene, copy number 24 (within-gene range 10–24): MAML3.
- chr4:139,794,125–164,384,050, 341 genes, copy number 16–24 (within-gene range 8–24) (broad region; genes not listed).
- chr14:22,630,929–22,644,352, 1 gene, copy number 15 (within-gene range 6–15): OR6J1.
- chr17:15,502,264–15,563,595, 1 gene, copy number 21 (within-gene range 8–21): TVP23C.
- chr17:15,565,483–22,706,703, 373 genes, copy number 16–41 (broad region; genes not listed).
- chr19:27,638,483–34,545,395, 152 genes, copy number 14–26 (broad region; genes not listed).
- chr19:37,467,585–37,730,733, 15 genes, copy number 17: ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3.
- chr21:18,477,358–18,760,320, 4 genes, copy number 13: AL109763.1, MIR548XHG, AF240627.1, MIR548X.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
